Somatic mutation profile of tumor specimen MP2PRT-PAPDYH-TMP1-A (aliquot MP2PRT-PAPDYH-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPDYH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,610 days).
Specimen MP2PRT-PAPDYH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 925d8cf5-1fbf-4226-8b0e-31b888d9073c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPDYH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPDYH-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d11306a1-7fb9-40f8-9a24-89ef95dc8dfe

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.8434G>A p.E2812K | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as rs936023498, COSV99949419; called by muse, mutect2
- ATXN1L | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 113/366 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1359529274; called by muse, mutect2, varscan2
- SPEM2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 215/691 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs765579933; called by muse, mutect2, varscan2
- TTF2 | c.2891G>A p.R964H | Missense Mutation (SNP) | VAF 160/408 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs546872594; called by muse, varscan2
- ANKRD36B | c.702del p.F234Lfs*3 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by pindel, varscan2
- BARD1 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 24/642 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.067); called by muse, mutect2
- CCDC197 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 108/533 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- CFAP46 | c.5446C>A p.Q1816K | Missense Mutation (SNP) | VAF 151/462 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- PARD6G | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 166/703 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- RASSF10 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 33/600 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- NT5DC3 | c.661C>T p.L221= | Silent (SNP) | VAF 120/318 reads (38%) | catalogued as rs1393384630; called by muse, mutect2, varscan2
- PCDHB16 | c.2127G>T p.V709= | Silent (SNP) | VAF 20/650 reads (3%) | catalogued as rs782077163; called by muse, mutect2
